Somatic mutation profile of tumor specimen MMRF_1881_1_BM_CD138pos (aliquot MMRF_1881_1_BM_CD138pos_T1_KBS5U_L05787) from MMRF case MMRF_1881, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.6 years (24,317 days).
Specimen MMRF_1881_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bae0493-ce87-4691-99a2-3c4b82cd3b14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1881_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1881_1_PB_Whole_C3_KBS5U_L05808; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe738626-c14f-4a6f-8cbc-418f382628c2

The open-access MAF lists 70 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 16, Silent 8, Intron 5, 3'Flank 3, Nonsense Mutation 2, RNA 2, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 101/266 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADD2 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as COSV52456514; called by muse, mutect2
- CNPY2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs886916815, COSV56264277; called by muse, mutect2, varscan2
- EP300 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1261612920; called by muse, mutect2
- FTMT | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs865797696, COSV58419985; called by muse, mutect2, varscan2
- GALNT3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200762567; called by muse, mutect2, varscan2
- IGHV2-70 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569950662; called by muse, varscan2
- IGLV3-1 | c.211A>T p.K71* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as rs371025428; called by muse, varscan2
- KAT6A | c.4393G>A p.D1465N | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs1193829737, COSV55904308; called by muse, mutect2, varscan2
- LGI4 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs769018578; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1354195107; called by muse, mutect2, varscan2
- OTOF | c.2524-1G>T p.X842_splice (on ENST00000272371 / NM_194248.3; = p.X95_splice on NM_004802.4) | Splice Site (SNP) | VAF 28/54 reads (52%) | catalogued as rs772510106; called by muse, mutect2, varscan2
- PLXNA4 | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780906661, COSV100324169; called by muse, mutect2, varscan2
- PLXNA4 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1315826602, COSV58118382; called by muse, mutect2, varscan2
- RYR3 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs753712777; called by muse, mutect2, varscan2
- SYNE1 | c.2536C>A p.Q846K (on ENST00000367255 / NM_182961.4; = p.Q853K on NM_033071.3) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV54913761; called by muse, mutect2, varscan2
- TEX2 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.319); catalogued as COSV99367097; called by muse, mutect2, varscan2
- ABCA6 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CBR1 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC66 | c.670C>A p.H224N (on ENST00000394672 / NM_001353147.1; = p.H190N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSPG4 | c.5375G>A p.G1792D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CYP4A11 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH6 | c.5815G>A p.G1939S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, varscan2
- EIF3J | c.148-7_148-3del | Splice Region (DEL) | VAF 50/145 reads (34%) | called by mutect2, pindel, varscan2
- EPB42 | c.293A>G p.D98G (on ENST00000441366 / NM_001114134.2; = p.D128G on NM_000119.3) | Missense Mutation (SNP) | VAF 117/170 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- HLA-DMA | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- INTS8 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- KALRN | c.7987C>A p.P2663T (on ENST00000360013 / NM_001024660.4; = p.P966T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- OR1I1 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGM2L1 | c.1610G>T p.S537I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- PHF3 | c.2049A>C p.L683F | Missense Mutation (SNP) | VAF 194/342 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PTPA | c.776G>C p.S259T (on ENST00000337738 / NM_178001.2; = p.S224T on NM_021131.5) | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPG7 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- STARD9 | c.8386G>A p.V2796I | Missense Mutation (SNP) | VAF 107/168 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- VPS13D | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPRIN2 | c.1227A>G p.E409= | Silent (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- CEP152 | c.3267A>G p.K1089= | Silent (SNP) | VAF 116/174 reads (67%) | catalogued as rs1020780910; called by muse, mutect2, varscan2
- DGKB | c.1617C>T p.Y539= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as rs762809124, COSV51767426; called by muse, mutect2, varscan2
- HBP1 | c.954G>A p.V318= | Silent (SNP) | VAF 74/151 reads (49%) | called by muse, mutect2, varscan2
- IGLL5 | c.115C>T p.L39= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, varscan2
- SOX8 | c.855C>T p.F285= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs778102734, COSV53510727; called by muse, mutect2, varscan2
- TNS2 | c.180C>T p.C60= (on ENST00000314250 / NM_170754.4; = p.C70= on NM_015319.2) | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs1340545633, COSV58578027; called by muse, mutect2, varscan2
- TOGARAM2 | c.1218C>T p.S406= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs111953532; called by muse, mutect2, varscan2
- ABL2 | c.220+30A>C | Intron (SNP) | VAF 93/215 reads (43%) | called by muse, mutect2, varscan2
- AMMECR1L | c.*1917G>A | 3'UTR (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ARHGEF37 | c.*1206dup | 3'UTR (INS) | VAF 78/143 reads (55%) | called by mutect2, pindel, varscan2
- CAMK1D | c.299+47C>G | Intron (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- CAVIN3 | c.*41C>A | 3'UTR (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1682C>A | RNA (SNP) | VAF 11/40 reads (28%) | catalogued as COSV67268758; called by muse, mutect2, varscan2
- COL5A1 | c.3528+12C>T | Intron (SNP) | VAF 17/53 reads (32%) | catalogued as rs927953209; called by muse, mutect2, varscan2
- DST | chr6:56458564 C>G | 3'Flank (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- ENPP6 | c.*1296C>T | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- ERC1 | c.*5157G>A | 3'UTR (SNP) | VAF 62/136 reads (46%) | called by muse, mutect2
- ERC1 | c.*5158A>G | 3'UTR (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2
- FAM227B | c.1013-24648C>T | Intron (SNP) | VAF 15/46 reads (33%) | catalogued as rs1480177391; called by muse, mutect2, varscan2
- FBRSL1 | c.*124C>T | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+2659C>T | Intron (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- FUT4 | c.*2234G>A | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- HCAR3 | c.*492G>A | 3'UTR (SNP) | VAF 34/228 reads (15%) | catalogued as rs536511393; called by muse, mutect2
- LINC02090 | n.382T>A | RNA (SNP) | VAF 19/29 reads (66%) | called by muse, mutect2, varscan2
- LPAR1 | chr9:110873677 A>C | 3'Flank (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- MFSD4B | c.-73G>A | 5'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1199412002; called by muse, mutect2
- PCDHB3 | c.*775G>T | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- PMP2 | c.*2342A>T | 3'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- PPAT | c.*704A>C | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- SIK1 | c.*1240del | 3'UTR (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- TMEM209 | c.*78A>G | 3'UTR (SNP) | VAF 17/225 reads (8%) | called by muse, mutect2
- TSPAN14 | chr10:80521410 G>A | 3'Flank (SNP) | VAF 42/69 reads (61%) | called by muse, mutect2, varscan2
- USP26 | c.*74C>T | 3'UTR (SNP) | VAF 15/15 reads (100%) | called by muse, mutect2, varscan2
- ZER1 | c.*184A>G | 3'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as rs74310390; called by muse, mutect2, varscan2
